Somatic mutation profile of tumor specimen TCGA-FS-A4F5-06A (aliquot TCGA-FS-A4F5-06A-11D-A25O-08) from TCGA case TCGA-FS-A4F5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.8 years (28,412 days).
Specimen TCGA-FS-A4F5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b73e01c2-8423-4fac-bfe0-2e54430e9098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A4F5-10B (Blood Derived Normal), aliquot TCGA-FS-A4F5-10B-01D-A25O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b8c72c4-b79c-4d5e-aad3-fda32c9f98ad

The open-access MAF lists 911 somatic variants for this specimen: 615 protein-altering or splice-affecting, 273 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 550, Silent 273, Nonsense Mutation 36, Splice Region 12, Splice Site 12, Intron 11, RNA 7, Frame Shift Del 5, 5'Flank 2, 3'UTR 2, 3'Flank 1.

Variants (750 of 911; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 97/126 reads (77%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 65/167 reads (39%) | catalogued as rs587778618, CM102799, COSV56221094, COSV56222163; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- AADACL2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.077); catalogued as COSV62929902, COSV62930179; called by muse, mutect2, varscan2
- ABCC11 | c.1387T>A p.Y463N | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV62322666; called by muse, mutect2, varscan2
- ABCC4 | c.1726C>T p.L576= | Splice Region (SNP) | VAF 5/24 reads (21%) | catalogued as COSV65311974; called by muse, mutect2
- ABCC6 | c.1638C>T p.V546= | Splice Region (SNP) | VAF 20/88 reads (23%) | catalogued as rs1011923791, COSV52741936; called by muse, mutect2, varscan2
- ABI3BP | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs377450718; called by muse, mutect2, varscan2
- ABI3BP | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52534377, COSV99425510; called by muse, mutect2, varscan2
- ABRA | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 164/293 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as rs1266381212, COSV61732062; called by muse, mutect2, varscan2
- ACACB | c.3685A>T p.I1229F | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV58132778; called by muse, mutect2, varscan2
- ACAD8 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs931572188, COSV55540009; called by muse, mutect2, varscan2
- ACAD8 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55540023; called by muse, mutect2, varscan2
- ACHE | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 62/102 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53816935; called by muse, mutect2, varscan2
- ACOXL | c.1439C>T p.S480F (on ENST00000389811 / NM_001371254.1; = p.S450F on NM_001142807.4) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV67735365; called by muse, mutect2, varscan2
- ACTL6B | c.822-1G>A p.X274_splice | Splice Site (SNP) | VAF 21/61 reads (34%) | catalogued as COSV50514480; called by muse, mutect2, varscan2
- ADAM21 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV50791526; called by muse, varscan2
- ADAM29 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63662912; called by muse, mutect2, varscan2
- ADAM29 | c.2227C>T p.P743S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.074); catalogued as COSV63662919; called by muse, mutect2, varscan2
- ADAM7 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51538749; called by muse, mutect2, varscan2
- ADAMTS16 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99941200; called by muse, mutect2, varscan2
- ADCY1 | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV52033485; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1319T>G p.V440G | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.248); catalogued as COSV58443091; called by muse, mutect2, varscan2
- ADGRB3 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV65382332, COSV65390606; called by muse, mutect2, varscan2
- ADGRE3 | c.1050+1G>A p.X350_splice | Splice Site (SNP) | VAF 8/26 reads (31%) | catalogued as rs1256206425, COSV53730097; called by muse, mutect2
- ADGRF3 | c.1139C>A p.S380Y (on ENST00000311519 / NM_001145168.1; = p.S181Y on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.492); catalogued as COSV61049862; called by muse, mutect2, varscan2
- ADGRF4 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.513); catalogued as rs200623239, COSV51949975; called by muse, mutect2, varscan2
- ADGRG4 | c.4579A>G p.K1527E | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV54954307; called by muse, mutect2, varscan2
- ADGRV1 | c.7490C>T p.A2497V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV67983634; called by muse, mutect2, varscan2
- AFF2 | c.3526G>A p.D1176N | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53986128; called by muse, mutect2, varscan2
- AHR | c.212G>A p.R71K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99619709; called by muse, mutect2, varscan2
- AHR | c.213G>T p.R71S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99619712; called by muse, mutect2, varscan2
- AL121899.2 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.044); catalogued as rs149044769; called by muse, mutect2, varscan2
- ALKBH7 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV55532090, COSV55532865; called by muse, mutect2, varscan2
- AMHR2 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as rs1159590841, COSV57685519; called by muse, mutect2, varscan2
- AMIGO2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 44/49 reads (90%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV56973154; called by muse, mutect2, varscan2
- ANGPT1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV52437907; called by muse, mutect2
- ANKRD30A | c.3124G>A p.D1042N (on ENST00000611781; = p.D986N on NM_052997.2) | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs772800090, COSV64603921, COSV64622668; called by muse, mutect2, varscan2
- ANKRD45 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); catalogued as rs753742210, COSV60960811; called by muse, mutect2, varscan2
- ANKS4B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs531162767, COSV61138806; called by muse, mutect2, varscan2
- ANO9 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.278); catalogued as COSV60383169; called by muse, mutect2, varscan2
- AOX1 | c.2707C>T p.L903F | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV65981251; called by muse, mutect2, varscan2
- AP3D1 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs756034211, COSV61427093; called by muse, mutect2, varscan2
- APOL5 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.879); catalogued as rs369479556; called by muse, mutect2, varscan2
- AQP1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV61266533; called by muse, mutect2, varscan2
- AQP3 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV53047911; called by muse, mutect2, varscan2
- ARHGAP29 | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867918256, COSV53110801; called by muse, mutect2, varscan2
- ARHGAP36 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV52265951; called by muse, mutect2, varscan2
- ARID2 | c.3937C>T p.Q1313* | Nonsense Mutation (SNP) | VAF 17/20 reads (85%) | catalogued as COSV57594803; called by muse, mutect2, varscan2
- ARSH | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV66962831; called by muse, mutect2, varscan2
- ASB4 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV57507323; called by muse, mutect2, varscan2
- ASB9 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV66851642; called by muse, mutect2, varscan2
- ASIC2 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV63303264; called by muse, mutect2, varscan2
- ASTN1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 198/416 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs866639170, COSV56061286; called by muse, mutect2, varscan2
- ASXL3 | c.3856C>T p.Q1286* | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV52463738; called by muse, mutect2, varscan2
- ATP7A | c.4421T>A p.L1474Q | Missense Mutation (SNP) | VAF 49/230 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as COSV58445194; called by muse, mutect2, varscan2
- AURKAIP1 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 93/135 reads (69%) | catalogued as COSV57939196; called by muse, mutect2, varscan2
- B3GLCT | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914062573, COSV58453355; called by muse, mutect2, varscan2
- BACH2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV57590341; called by muse, mutect2, varscan2
- BCAN | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV61256557; called by muse, mutect2, varscan2
- BCL3 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 182/309 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs745458470, COSV51234121; called by muse, mutect2, varscan2
- BCL9L | c.2972C>T p.S991L | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1167485556, COSV52683762; called by muse, mutect2, varscan2
- BCORL1 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54394768; called by muse, mutect2, varscan2
- BMP5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63702532, COSV63706127; called by muse, mutect2, varscan2
- BPIFA2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV53610868; called by muse, mutect2, varscan2
- BPIFB3 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.769); catalogued as COSV64957206; called by muse, mutect2, varscan2
- BTBD1 | c.1421A>G p.Q474R | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55602701; called by muse, mutect2, varscan2
- BTBD11 | c.2053G>A p.E685K (on ENST00000280758 / NM_001018072.2; = p.E222K on NM_001017523.2) | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760476113, COSV55022926; called by muse, mutect2, varscan2
- BTBD11 | c.2729C>T p.S910L (on ENST00000280758 / NM_001018072.2; = p.S447L on NM_001017523.2) | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1399821045, COSV55022933; called by muse, mutect2, varscan2
- C16orf89 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as COSV60123431; called by muse, mutect2, varscan2
- C17orf80 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.479); catalogued as COSV52145906; called by muse, mutect2, varscan2
- C1QA | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV65889496; called by muse, mutect2, varscan2
- C1QB | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV59245286; called by muse, mutect2, varscan2
- C1QTNF2 | c.733G>A p.D245N (on ENST00000393975; = p.D200N on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs752487351, COSV67432497; called by muse, mutect2, varscan2
- C1QTNF7 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 125/310 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54852140; called by muse, mutect2, varscan2
- C1R | c.1778C>T p.P593L (on ENST00000536053 / NM_001354346.2; = p.P579L on NM_001733.7) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73382922; called by muse, mutect2, varscan2
- C6 | c.86G>A p.W29* | Nonsense Mutation (SNP) | VAF 65/145 reads (45%) | catalogued as COSV54709072; called by muse, mutect2, varscan2
- C8orf34 | c.349A>G p.T117A | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs778292497, COSV61377493; called by muse, mutect2, varscan2
- CACNG3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as rs1426360236, COSV50064945; called by muse, mutect2, varscan2
- CAMTA1 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57887236, COSV57906544; called by muse, mutect2, varscan2
- CAPN2 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs769605419, COSV99688915; called by muse, mutect2, varscan2
- CARD11 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62754888; called by muse, mutect2, varscan2
- CBFA2T3 | c.172A>T p.K58* | Nonsense Mutation (SNP) | VAF 30/49 reads (61%) | catalogued as rs572358958, COSV51925966; called by muse, mutect2, varscan2
- CBLL2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV60368461; called by muse, mutect2, varscan2
- CCDC141 | c.4073C>T p.T1358I | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV55372368; called by muse, mutect2, varscan2
- CCDC178 | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV55770174; called by muse, mutect2, varscan2
- CCDC33 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51499737; called by muse, mutect2
- CCDC8 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as COSV56773011; called by muse, mutect2, varscan2
- CCL2 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as COSV56773471; called by muse, mutect2, varscan2
- CCR7 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV55849013; called by muse, mutect2, varscan2
- CD1A | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV56861445; called by muse, mutect2, varscan2
- CD1C | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as rs145638725, COSV63805710, COSV63806016; called by muse, mutect2, varscan2
- CD22 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.017); catalogued as COSV50051713, COSV99323739; called by muse, mutect2, varscan2
- CD86 | c.278G>A p.W93* (on ENST00000330540 / NM_175862.5; = p.W87* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV52604952; called by muse, mutect2, varscan2
- CDH13 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.654); catalogued as COSV51800112; called by muse, mutect2, varscan2
- CDH18 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963132, COSV56899350; called by muse, mutect2, varscan2
- CDH2 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52271652; called by mutect2, varscan2
- CDH20 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53008516; called by muse, mutect2, varscan2
- CDH6 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54068397; called by muse, mutect2, varscan2
- CDH7 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59884853; called by muse, mutect2, varscan2
- CEACAM19 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.396); catalogued as COSV100715444; called by muse, mutect2, varscan2
- CEP131 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53952444; called by muse, mutect2
- CEP55 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV65184958; called by muse, mutect2, varscan2
- CERS3 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.84); PolyPhen benign (0.315); catalogued as COSV52565710, COSV52567447, COSV52569502; called by muse, mutect2, varscan2
- CFAP251 | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 39/43 reads (91%) | catalogued as rs1018120311, COSV56609735; called by muse, mutect2, varscan2
- CFAP53 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 33/117 reads (28%) | catalogued as COSV68351824; called by muse, mutect2, varscan2
- CFH | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV62777161; called by muse, mutect2, varscan2
- CGB7 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62281848; called by muse, mutect2, varscan2
- CGNL1 | c.1459C>T p.L487F | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs144501542; called by muse, mutect2, varscan2
- CHD6 | c.7987G>A p.D2663N | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.494); catalogued as rs751303308, COSV64690019; called by muse, mutect2, varscan2
- CILP2 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52274324; called by muse, mutect2, varscan2
- CIP2A | c.2587C>T p.R863C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs771105116, COSV55418375; called by muse, mutect2, varscan2
- CITED1 | c.61-1G>A p.X21_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99860329; called by muse, mutect2, varscan2
- CLCN1 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1554438576, COSV58369268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN5 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583558; called by muse, mutect2, varscan2
- CLDN10 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as rs763024030, COSV65297205; called by muse, mutect2, varscan2
- CLIC6 | c.1630G>A p.E544K (on ENST00000360731 / NM_001317009.2; = p.E526K on NM_053277.3) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759018451, COSV62447482; called by muse, mutect2, varscan2
- CLVS2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.077); catalogued as COSV51561093; called by muse, mutect2, varscan2
- CNR1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); catalogued as COSV62986979, COSV62990918; called by muse, mutect2, varscan2
- COL11A2 | c.4378C>T p.P1460S (on ENST00000341947 / NM_080680.3; = p.P1353S on NM_080679.2) | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1043741488, COSV100554326, COSV59496038; called by muse, mutect2, varscan2
- COL12A1 | c.6037G>A p.G2013R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs772738706, COSV59394305; called by muse, mutect2, varscan2
- COL22A1 | c.2024G>A p.G675E | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57333468, COSV57342391; called by muse, mutect2, varscan2
- COL22A1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs778721884, COSV57333474; called by muse, mutect2, varscan2
- COL3A1 | c.3658T>A p.Y1220N | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.497); catalogued as COSV58586189; called by muse, mutect2, varscan2
- COL4A4 | c.3611G>A p.G1204E | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61631419; called by muse, mutect2
- COL8A1 | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53732984; called by muse, mutect2, varscan2
- COL9A1 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as rs1562303329, COSV57882516; called by muse, mutect2, varscan2
- COL9A1 | c.653C>T p.A218V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV61831360; called by muse, mutect2, varscan2
- COL9A1 | c.404A>G p.D135G | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1202257253, COSV61831365; called by muse, mutect2, varscan2
- COQ8B | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV54686617; called by muse, mutect2, varscan2
- COX10 | c.629T>C p.F210S | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV55404517; called by muse, mutect2, varscan2
- CPN2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.321); catalogued as rs375218643; called by muse, mutect2, varscan2
- CPNE4 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.989); catalogued as COSV70193306; called by muse, mutect2, varscan2
- CPXM2 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.22); PolyPhen benign (0.101); catalogued as COSV53860438; called by muse, mutect2, varscan2
- CRHR2 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV59264843; called by muse, mutect2, varscan2
- CROCC | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV65011578; called by muse, mutect2, varscan2
- CSMD1 | c.8017G>A p.E2673K (on ENST00000520002; = p.E2672K on NM_033225.6) | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as rs762951826, COSV59312630; called by muse, varscan2
- CSMD1 | c.7886C>T p.P2629L (on ENST00000520002; = p.P2628L on NM_033225.6) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs1453668081, COSV59312653; called by muse, varscan2
- CSMD2 | c.4337G>A p.G1446E | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53904459; called by muse, mutect2, varscan2
- CSMD3 | c.9615G>A p.M3205I (on ENST00000297405 / NM_001363185.1; = p.M3036I on NM_052900.3) | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV52159086, COSV52258128; called by muse, mutect2, varscan2
- CTNND2 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV58882626; called by muse, varscan2
- CUL4B | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs757896094, COSV68137453; called by muse, mutect2, varscan2
- CUZD1 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV59026300; called by muse, mutect2, varscan2
- CYP19A1 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs1355677689, COSV53058776; called by muse, mutect2, varscan2
- CYP4A11 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60223132; called by muse, mutect2, varscan2
- CYP4F3 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as rs756680758, COSV55409152; called by muse, mutect2, varscan2
- CYP4F8 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV57853859; called by muse, mutect2, varscan2
- DACH1 | c.1324C>T p.P442S (on ENST00000619232 / NM_001366712.1; = p.P390S on NM_080759.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.742); catalogued as rs747753827, COSV57493215; called by muse, mutect2, varscan2
- DACH2 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1169916424, COSV64169409; called by muse, mutect2, varscan2
- DBF4B | c.1724C>T p.T575I | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV59262144; called by muse, mutect2, varscan2
- DCP1B | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54968557; called by muse, mutect2, varscan2
- DDR1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61320778; called by muse, mutect2, varscan2
- DDX27 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV65629514; called by muse, mutect2
- DIAPH3 | c.2650C>T p.H884Y (on ENST00000400324 / NM_001042517.2; = p.H621Y on NM_030932.3) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57367818, COSV57368931; called by muse, mutect2, varscan2
- DNAH10 | c.2032G>A p.E678K (on ENST00000409039; = p.E617K on NM_207437.3) | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV68992102; called by muse, mutect2, varscan2
- DNAJB8 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs374415635; called by muse, mutect2, varscan2
- DNAJC5B | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV52537036; called by muse, mutect2, varscan2
- DNER | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs267599247, COSV59164458; called by muse, mutect2, varscan2
- DOK6 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.962); catalogued as COSV101234492, COSV66929801; called by muse, mutect2, varscan2
- DSCAM | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV68024842; called by muse, mutect2, varscan2
- DSCAM | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68025372; called by muse, mutect2, varscan2
- DTNA | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1160999097, COSV52000112; called by muse, mutect2, varscan2
- DYRK3 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65605934; called by muse, mutect2, varscan2
- DZIP3 | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 69/116 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as COSV64311796; called by muse, mutect2, varscan2
- EBF2 | c.1437G>A p.M479I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV68777236; called by muse, mutect2, varscan2
- EFCAB6 | c.4372G>A p.D1458N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs750687549, COSV53061827; called by muse, mutect2, varscan2
- EFEMP1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV62615830; called by muse, mutect2, varscan2
- EHD3 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235628529, COSV59030177; called by muse, mutect2, varscan2
- EMILIN3 | c.291-1G>A p.X97_splice | Splice Site (SNP) | VAF 37/59 reads (63%) | catalogued as COSV60035859; called by muse, mutect2, varscan2
- ENPEP | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54448292; called by muse, mutect2, varscan2
- EPHA1 | c.2917G>A p.G973R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs771427284, COSV51970668; called by muse, mutect2
- EPHA1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 147/262 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV51970681; called by muse, mutect2, varscan2
- EPHA6 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as rs1483105928, COSV67569289; called by muse, mutect2, varscan2
- EPHA7 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as rs776583281, COSV65178939, COSV65182030; called by muse, mutect2, varscan2
- EPHA7 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV65168482; called by muse, mutect2, varscan2
- EPS15L1 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV99933065; called by muse, mutect2, varscan2
- EPS15L1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV99933067; called by muse, mutect2, varscan2
- ERN2 | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 139/285 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139320105; called by muse, mutect2, varscan2
- ESRRG | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750331242, COSV63158253, COSV63168875; called by muse, mutect2, varscan2
- EXOC6B | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs528718114, COSV55552318; called by muse, mutect2, varscan2
- EYS | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1562221347, COSV60983093, COSV60990936; called by muse, mutect2, varscan2
- F13B | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV66373488; called by muse, mutect2, varscan2
- F9 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs867548424, COSV54378854; called by muse, mutect2, varscan2
- FAM131B | c.200T>A p.M67K | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV68125893; called by muse, mutect2, varscan2
- FAM155B | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.917); catalogued as COSV52935889; called by muse, mutect2, varscan2
- FAM160A2 | c.2452C>T p.P818S (on ENST00000449352 / NM_001098794.2; = p.P832S on NM_032127.4) | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs1259599911, COSV56410937; called by muse, mutect2, varscan2
- FAM71B | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759711929, COSV57227977, COSV57228705; called by muse, mutect2, varscan2
- FAM81B | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.108); catalogued as COSV51982189; called by muse, mutect2, varscan2
- FANCB | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as COSV60759545; called by muse, mutect2, varscan2
- FAP | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51861200; called by muse, mutect2, varscan2
- FAT1 | c.11203C>T p.Q3735* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV101499347; called by muse, mutect2, varscan2
- FAT3 | c.9376G>A p.D3126N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53101471; called by muse, mutect2, varscan2
- FAT4 | c.5221C>T p.P1741S | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as COSV58680927; called by muse, mutect2, varscan2
- FILIP1 | c.2153G>A p.R718Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs776854335, COSV52727783; called by muse, mutect2, varscan2
- FILIP1 | c.1253G>A p.S418N | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as rs1431392749, COSV52727811; called by muse, mutect2, varscan2
- FLAD1 | c.1235T>C p.L412P | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52696704; called by muse, mutect2, varscan2
- FLG | c.8773G>A p.D2925N | Missense Mutation (SNP) | VAF 56/368 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV100910564; called by muse, mutect2, varscan2
- FLG2 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV66166901; called by muse, mutect2, varscan2
- FMO3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs866502499, COSV63006994; called by muse, mutect2, varscan2
- FN1 | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV60551196; called by muse, mutect2, varscan2
- FOXK2 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs764910135, COSV100082076; called by muse, mutect2, varscan2
- FRMD7 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV53745711; called by muse, mutect2, varscan2
- FRMPD3 | c.4721C>T p.T1574I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52189289; called by muse, mutect2, varscan2
- FRMPD4 | c.1886C>T p.S629F | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV66211345; called by muse, mutect2, varscan2
- FRY | c.7768G>T p.E2590* | Nonsense Mutation (SNP) | VAF 28/48 reads (58%) | catalogued as COSV66568795, COSV66574139; called by muse, mutect2, varscan2
- FSCN3 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs370690397; called by muse, mutect2, varscan2
- FUNDC2 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1342355580, COSV65670778; called by muse, mutect2, varscan2
- GAB1 | c.1772C>A p.P591H | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV53756041; called by muse, mutect2, varscan2
- GABRE | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64818853; called by muse, mutect2, varscan2
- GABRG2 | c.1384G>A p.E462K (on ENST00000361925 / NM_001375343.1; = p.E422K on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV62717413, COSV62723138; called by muse, mutect2, varscan2
- GAS2L1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs538581500, COSV99329514; called by muse, varscan2
- GAS2L1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV99329517; called by muse, mutect2, varscan2
- GBP2 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65069122; called by mutect2, varscan2
- GDPD2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.095); catalogued as COSV65532706; called by muse, mutect2, varscan2
- GGT5 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763495821, COSV54069750; called by muse, mutect2, varscan2
- GIMAP8 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 55/86 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV56229860; called by muse, mutect2, varscan2
- GLDN | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59089783; called by muse, mutect2, varscan2
- GLMP | c.698T>C p.L233P | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as COSV55294704; called by muse, mutect2, varscan2
- GPAT3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as COSV52356538; called by muse, mutect2, varscan2
- GPATCH8 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.276); catalogued as COSV59194383; called by muse, mutect2, varscan2
- GPR176 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 87/147 reads (59%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1408503851, COSV54444619; called by muse, mutect2, varscan2
- GPR34 | c.608T>G p.M203R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as COSV59365423; called by muse, mutect2, varscan2
- GPX5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69079309; called by muse, mutect2, varscan2
- GRIK2 | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as COSV59729905; called by muse, mutect2, varscan2
- GRIN2A | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV58019197; called by muse, mutect2, varscan2
- GRM7 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); catalogued as COSV63140312; called by muse, mutect2, varscan2
- GRM8 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs143468706; called by muse, mutect2, varscan2
- GSPT2 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61214138; called by muse, mutect2, varscan2
- GZMA | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.199); catalogued as COSV57051647, COSV57058778, COSV99696602; called by muse, mutect2, varscan2
- HAPLN1 | c.66T>G p.Y22* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV57147170; called by muse, mutect2, varscan2
- HECW1 | c.3215G>A p.R1072Q | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1008402690, COSV67822336; called by muse, mutect2, varscan2
- HFM1 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs199692136; called by muse, mutect2, varscan2
- HIVEP2 | c.5188A>T p.M1730L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV50009375; called by muse, mutect2, varscan2
- HIVEP3 | c.5221G>A p.E1741K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56013963; called by muse, mutect2, varscan2
- HLA-DRA | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV66622459; called by muse, mutect2, varscan2
- HNF4G | c.472C>T p.P158S (on ENST00000354370 / NM_001330561.2; = p.P205S on NM_004133.5) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV62967405; called by muse, mutect2, varscan2
- HNF4G | c.906G>A p.M302I (on ENST00000354370 / NM_001330561.2; = p.M349I on NM_004133.5) | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV62967417; called by muse, mutect2, varscan2
- HOATZ | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60441225; called by muse, mutect2, varscan2
- HTT | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.185); catalogued as COSV61860921; called by muse, mutect2, varscan2
- HYDIN | c.11525A>T p.E3842V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV66638543; called by muse, varscan2
- HYDIN | c.6993G>A p.K2331= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99992884; called by mutect2, varscan2
- IBSP | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as rs1171736771, COSV56895374, COSV56896198; called by muse, mutect2, varscan2
- IFT46 | c.430C>T p.P144S (on ENST00000264021 / NM_001168618.2; = p.P195S on NM_020153.3) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV50594189; called by muse, mutect2, varscan2
- IGHV1-3 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 18/22 reads (82%) | catalogued as rs1324173467; called by muse, mutect2, varscan2
- IGKV1D-42 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as rs757241359; called by muse, mutect2, varscan2
- IKZF3 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1428090962, COSV53099562; called by muse, mutect2, varscan2
- IL10RA | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57140316; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1656G>A p.W552* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV56254744; called by muse, mutect2, varscan2
- IL1RL1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.026); catalogued as COSV52114978; called by muse, mutect2, varscan2
- IL1RL2 | c.244T>A p.F82I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV51814649; called by muse, mutect2, varscan2
- IMPG1 | c.2044+1G>A p.X682_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100886390; called by muse, mutect2
- INSR | c.3389C>T p.P1130L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.14); catalogued as COSV57161375; called by muse, mutect2, varscan2
- INSRR | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 15/34 reads (44%) | catalogued as rs552398222, COSV63872477; called by muse, mutect2, varscan2
- IQCB1 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV60437095; called by muse, mutect2, varscan2
- IQSEC2 | c.1031C>T p.S344F (on ENST00000642864 / NM_001111125.3; = p.S139F on NM_015075.2) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.165); catalogued as COSV64724947; called by muse, mutect2, varscan2
- IQUB | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV61238723; called by muse, mutect2, varscan2
- IST1 | c.842C>T p.P281L (on ENST00000535424 / NM_001270976.1; = p.P268L on NM_014761.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61709407; called by muse, mutect2, varscan2
- ISX | c.382-1G>A p.X128_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as COSV58086033, COSV58086313; called by muse, mutect2, varscan2
- ITGA2 | c.501G>A p.Q167= | Splice Region (SNP) | VAF 27/53 reads (51%) | catalogued as rs768753137, COSV56858841; called by muse, mutect2, varscan2
- ITGA4 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as COSV51999064; called by muse, mutect2, varscan2
- ITGA7 | c.2786G>A p.G929D (on ENST00000555728; = p.G885D on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as rs1408441996, COSV57694271; called by muse, mutect2, varscan2
- ITGAX | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1281916256, COSV51644908, COSV51645334; called by muse, mutect2, varscan2
- ITPR1 | c.3847C>T p.Q1283* (on ENST00000354582; = p.Q1268* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as COSV56978135; called by muse, mutect2, varscan2
- JCAD | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 81/91 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64759205; called by muse, mutect2, varscan2
- JHY | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56219006; called by muse, mutect2, varscan2
- JPH1 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as COSV60610280; called by muse, mutect2, varscan2
- KCNC2 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV54367411; called by muse, mutect2, varscan2
- KCNH1 | c.823G>A p.G275R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779913410, COSV55078317; called by muse, mutect2, varscan2
- KCNH7 | c.465G>A p.R155= | Splice Region (SNP) | VAF 9/22 reads (41%) | catalogued as COSV59794266; called by muse, mutect2, varscan2
- KCNMB4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); catalogued as COSV50691172; called by muse, mutect2
- KCNQ3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs774311301, COSV66468995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT1 | c.3653C>T p.S1218L (on ENST00000488444; = p.S1223L on NM_020822.3) | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as rs779379200, COSV53700029; ClinVar: likely benign; called by muse, mutect2, varscan2
- KHDRBS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.964); catalogued as rs868714236, COSV55428923; called by mutect2, varscan2
- KIF1B | c.4907C>T p.P1636L (on ENST00000377086 / NM_001365952.1; = p.P1590L on NM_015074.3) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV55807637; called by muse, mutect2, varscan2
- KIFC1 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 60/315 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100995989, COSV65728936; called by muse, mutect2, varscan2
- KLHL4 | c.1618G>T p.V540L | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV64140364; called by muse, mutect2
- KPRP | c.761G>A p.R254K | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV64221471; called by muse, mutect2, varscan2
- KRBA1 | c.557G>A p.R186K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); catalogued as COSV55441101; called by muse, mutect2, varscan2
- KRT6B | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as rs1211806889, COSV52883258; called by muse, mutect2, varscan2
- KRT9 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 11/37 reads (30%) | PolyPhen benign (0.012); catalogued as rs765577453, COSV55852582; called by muse, mutect2
- LAMA2 | c.6547C>T p.L2183F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140574226; called by muse, mutect2, varscan2
- LCA5 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.966); catalogued as rs374135825; called by muse, mutect2, varscan2
- LMF1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as rs758773994, COSV51896210; called by muse, mutect2, varscan2
- LRBA | c.4226G>A p.R1409K | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1284493439, COSV63953630; called by muse, mutect2, varscan2
- LRIG2 | c.1175T>C p.I392T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs764118448, COSV63161706; called by muse, mutect2, varscan2
- LRRC37A3 | c.4432A>G p.T1478A | Missense Mutation (SNP) | VAF 111/190 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV58534993; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2, varscan2
- LRRC61 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 60/101 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56231109; called by muse, mutect2, varscan2
- LRRN1 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV60013546; called by muse, mutect2, varscan2
- LSM11 | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770812064, COSV53848038; called by muse, mutect2, varscan2
- LYN | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV70205578; called by muse, mutect2, varscan2
- MAGEA12 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.791); catalogued as COSV63295641; called by muse, mutect2, varscan2
- MAGEA12 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.91); catalogued as COSV100756925; called by muse, mutect2, varscan2
- MAGEB16 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.566); catalogued as COSV67873493; called by muse, mutect2
- MAGEB3 | c.845A>G p.E282G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64396977; called by muse, mutect2, varscan2
- MAML2 | c.1609C>T p.L537F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as COSV73263235; called by muse, mutect2, varscan2
- MAOA | c.347G>A p.W116* | Nonsense Mutation (SNP) | VAF 17/88 reads (19%) | catalogued as COSV58642555; called by muse, mutect2, varscan2
- MAP2K7 | c.1080-1G>A p.X360_splice | Splice Site (SNP) | VAF 22/67 reads (33%) | catalogued as COSV67607575, COSV67608040; called by muse, mutect2, varscan2
- MAP3K13 | c.660-1G>C p.X220_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99407164; called by muse, mutect2, varscan2
- MAP3K13 | c.660G>T p.K220N | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV99407167; called by muse, mutect2, varscan2
- MAP3K5 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs145735047, COSV62886989; called by muse, mutect2, varscan2
- MAP7D3 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.107); catalogued as COSV60170699; called by muse, mutect2, varscan2
- MBD3 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50083368; called by muse, mutect2, varscan2
- MCTP2 | c.229T>C p.S77P | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV59143225; called by muse, mutect2, varscan2
- MDFIC | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 21/44 reads (48%) | catalogued as COSV99995137; called by muse, mutect2, varscan2
- MDGA1 | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs1241313767, COSV51794945; called by muse, mutect2, varscan2
- MET | c.1627G>A p.D543N | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs763991073, COSV59260226; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAM | c.3497C>T p.S1166F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.53); catalogued as rs866572586, COSV72074490; called by muse, mutect2, varscan2
- MGAM | c.4189G>A p.E1397K | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs777169037, COSV72074491; called by muse, mutect2, varscan2
- MIP | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as COSV57788324; called by muse, mutect2, varscan2
- MKRN2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 122/216 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50104590; called by muse, mutect2, varscan2
- MLIP | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1334731220, COSV51428887; called by muse, mutect2, varscan2
- MMEL1 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56520776; called by muse, mutect2, varscan2
- MMP12 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58259633; called by muse, mutect2
- MMP13 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52823706; called by muse, mutect2, varscan2
- MPO | c.888C>T p.I296= | Splice Region (SNP) | VAF 23/69 reads (33%) | catalogued as COSV56563228; called by muse, mutect2, varscan2
- MRGPRX4 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58590365; called by muse, mutect2, varscan2
- MRPL23 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV67413864; called by mutect2, varscan2
- MRPS22 | c.569G>A p.R190Q (on ENST00000310776 / NM_001363893.1; = p.R191Q on NM_020191.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs768880732, CM165938, COSV60349667; called by muse, mutect2, varscan2
- MS4A14 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100279536; called by muse, mutect2
- MS4A14 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886223376, COSV55732376; called by muse, mutect2
- MSR1 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as rs1254025277, COSV50509993; called by muse, mutect2, varscan2
- MTM1 | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs782364557, COSV60334680; called by muse, mutect2, varscan2
- MTUS2 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV70916396; called by muse, mutect2, varscan2
- MUC16 | c.33416C>T p.S11139L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.439); catalogued as COSV67461322, COSV67464063; called by muse, mutect2, varscan2
- MUC16 | c.29548G>A p.D9850N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV67461333; called by muse, mutect2
- MUC16 | c.12194C>T p.S4065F | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.319); catalogued as COSV67461344; called by muse, mutect2, varscan2
- MUC17 | c.7150G>A p.D2384N | Missense Mutation (SNP) | VAF 66/306 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs577539877, COSV60286368; called by muse, varscan2
- MUC21 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 68/285 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as COSV66220640; called by muse, mutect2, varscan2
- MUC21 | c.1247G>A p.G416E | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as rs55803740, COSV66220645; called by muse, mutect2, varscan2
- MUC4 | c.13806G>A p.W4602* (on ENST00000463781 / NM_018406.7; = p.W366* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV57777457; called by muse, mutect2, varscan2
- MXRA5 | c.4954C>T p.P1652S | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.503); catalogued as rs371923940, COSV54230873; called by muse, mutect2, varscan2
- MYB | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV57197764; called by muse, mutect2, varscan2
- MYBPC2 | c.2215G>A p.E739K | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV63093809; called by muse, varscan2
- MYH4 | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55116798; called by muse, mutect2, varscan2
- MYH4 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776140827, COSV55116809; called by muse, mutect2, varscan2
- MYH6 | c.2566G>A p.E856K | Missense Mutation (SNP) | VAF 51/55 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV62449646; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2, varscan2
- MYO18B | c.6023C>T p.S2008L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV59131821; called by muse, varscan2
- MYO5C | c.4252T>C p.S1418P | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV55905199; called by muse, mutect2, varscan2
- MYOCD | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs767925734, COSV58498174, COSV58501218; called by muse, mutect2, varscan2
- MYOF | c.3876G>A p.M1292I | Missense Mutation (SNP) | VAF 29/31 reads (94%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs1365976753, COSV63703102; called by muse, mutect2, varscan2
- MYOM3 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV58392751, COSV58395160; called by muse, mutect2, varscan2
- MYT1L | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV67710462; called by muse, mutect2, varscan2
- NALCN | c.2119-2A>C p.X707_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51930911; called by muse, mutect2, varscan2
- NALCN | c.945C>T p.N315= | Splice Region (SNP) | VAF 12/21 reads (57%) | catalogued as rs761273502, COSV51914852, COSV51930921; called by muse, mutect2, varscan2
- NES | c.4000C>T p.P1334S | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); catalogued as COSV63960822; called by muse, mutect2, varscan2
- NEU3 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV53636349; called by muse, mutect2, varscan2
- NEUROD1 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV54548977; called by muse, mutect2, varscan2
- NEXMIF | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50027881; called by muse, mutect2, varscan2
- NHSL2 | c.1603A>G p.T535A (on ENST00000510661; = p.T901A on NM_001013627.2) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV65453172; called by muse, mutect2, varscan2
- NLRC4 | c.1559G>A p.G520E | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.381); catalogued as COSV61592294; called by muse, mutect2, varscan2
- NLRP11 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV64086848; called by muse, mutect2, varscan2
- NLRP13 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs150988752; called by muse, mutect2, varscan2
- NOD2 | c.1881A>T p.R627S | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.162); catalogued as COSV56049847; called by muse, mutect2, varscan2
- NOP14 | c.2125C>T p.H709Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as COSV100054636; called by muse, mutect2, varscan2
- NPAP1 | c.3037A>G p.T1013A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61505157; called by muse, mutect2, varscan2
- NPAS2 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.222); catalogued as rs1201624404, COSV59557145; called by muse, mutect2, varscan2
- NPY1R | c.439G>T p.G147W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56714206; called by muse, mutect2, varscan2
- NPY5R | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs780119025, COSV58451006, COSV58451742; called by muse, mutect2, varscan2
- NXF1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53672955; called by muse, mutect2, varscan2
- OAS1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV52535299; called by muse, mutect2, varscan2
- OR10G7 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs1253874078, COSV57866816; called by muse, mutect2, varscan2
- OR10S1 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV73342750; called by muse, mutect2, varscan2
- OR1A1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs1312530493, COSV58403599; called by muse, mutect2, varscan2
- OR2A2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 146/262 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs759840581, COSV68870991, COSV68871204; called by muse, mutect2
- OR2F1 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | catalogued as COSV67330827; called by muse, mutect2, varscan2
- OR2M2 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV62898183; called by muse, mutect2, varscan2
- OR51Q1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56178602; called by muse, mutect2, varscan2
- OR51S1 | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV59058120; called by muse, mutect2, varscan2
- OR52B6 | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs759601138, COSV61447727; called by muse, mutect2, varscan2
- OR52L1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs867894367, COSV59985811; called by muse, mutect2, varscan2
- OR5B21 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as rs762734256, COSV64481789; called by muse, mutect2, varscan2
- OR5D18 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV61736907; called by muse, mutect2, varscan2
- OR5H6 | c.907C>T p.P303S (on ENST00000642105; = p.P287S on NM_001005479.2) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs765590709, COSV67351337; called by muse, mutect2, varscan2
- OR5L1 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1486213468, COSV100450338, COSV61733603; called by muse, mutect2, varscan2
- OR5M8 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59115605; called by muse, mutect2, varscan2
- OR8H3 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as COSV100539100, COSV57908586; called by muse, mutect2, varscan2
- OR9Q1 | c.92T>A p.F31Y | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59039522; called by muse, varscan2
- OTOP3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV60913158; called by muse, mutect2, varscan2
- OTOP3 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs868785940, COSV60912533; called by muse, mutect2, varscan2
- PAK4 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58944727; called by muse, mutect2, varscan2
- PAK5 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as COSV62025802, COSV62038311; called by muse, mutect2, varscan2
- PALLD | c.2749G>A p.E917K (on ENST00000505667 / NM_001166108.2; = p.E900K on NM_016081.4) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs372708613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPPA2 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs775169340, COSV62776814, COSV62779600; called by muse, varscan2
- PARP15 | c.1141G>A p.G381R (on ENST00000464300 / NM_001113523.3; = p.G147R on NM_152615.2) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV59972285; called by muse, mutect2, varscan2
- PBXIP1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100869976, COSV63777039; called by muse, mutect2, varscan2
- PCDHA12 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as rs782151232, COSV56494874; called by muse, mutect2, varscan2
- PCDHB3 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 43/57 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.169); catalogued as rs267600412, COSV50581081; called by muse, mutect2, varscan2
- PCDHB6 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 110/128 reads (86%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV50694438; called by muse, mutect2, varscan2
- PCDHB8 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.02); catalogued as COSV50762962; called by muse, mutect2, varscan2
- PCGF5 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV60237756; called by muse, mutect2, varscan2
- PCLO | c.14728G>A p.E4910K | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs751146334, COSV61629563; called by muse, mutect2, varscan2
- PCLO | c.7718C>T p.S2573F | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV61629593; called by muse, mutect2, varscan2
- PCLO | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV100438594, COSV61629629; called by muse, mutect2, varscan2
- PCSK4 | c.1068C>T p.I356= | Splice Region (SNP) | VAF 12/24 reads (50%) | catalogued as rs772084886, COSV99278640; called by muse, varscan2
- PCSK9 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56161778; called by muse, mutect2, varscan2
- PDE1A | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs775065809, COSV59521241; called by muse, mutect2, varscan2
- PDE1C | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as rs1018039717, COSV58511496; called by muse, mutect2, varscan2
- PDK3 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs375475050, COSV64793308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDS5A | c.2716C>T p.H906Y | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as COSV57824988; called by muse, mutect2, varscan2
- PDZK1 | c.1453A>T p.K485* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as COSV58259009; called by muse, mutect2, varscan2
- PEF1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.354); catalogued as COSV65483622; called by muse, mutect2, varscan2
- PHIP | c.4031C>T p.P1344L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290635325, COSV51503713, COSV99244043; called by muse, mutect2, varscan2
- PHKG2 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1289451316, COSV60311665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHLDB3 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs984209862, COSV52669057; called by muse, mutect2
- PIK3C3 | c.2649G>A p.Q883= | Splice Region (SNP) | VAF 4/22 reads (18%) | catalogued as COSV56278391; called by muse, mutect2, varscan2
- PKD1 | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51914529; called by muse, mutect2, varscan2
- PLA2G4C | c.474G>A p.M158I | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV62785099; called by muse, mutect2, varscan2
- PLA2G4D | c.255+1G>A p.X85_splice | Splice Site (SNP) | VAF 38/140 reads (27%) | catalogued as rs767771463, COSV51820320; called by muse, mutect2, varscan2
- PLA2R1 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV51777599; called by muse, mutect2, varscan2
- PLB1 | c.698G>A p.S233N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as COSV59823486; called by muse, mutect2, varscan2
- PLCH1 | c.2066G>A p.R689Q (on ENST00000340059 / NM_001130960.2; = p.R701Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs894808426, COSV58193990; called by muse, mutect2, varscan2
- PLCH1 | c.1229G>A p.G410E (on ENST00000340059 / NM_001130960.2; = p.G422E on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58192957; called by muse, mutect2, varscan2
- PLCL1 | c.2479C>T p.P827S | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs763859785, COSV70826791; called by muse, mutect2, varscan2
- PLD1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747369339, COSV100578924, COSV60565840; called by muse, mutect2, varscan2
- PLD5 | c.1300T>A p.F434I (on ENST00000442594; = p.F372I on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100140394; called by muse, mutect2, varscan2
- PLEKHS1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV63054796; called by muse, mutect2
- PLK3 | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59501184; called by muse, mutect2
- PLK3 | c.438C>T p.S146= | Splice Region (SNP) | VAF 10/48 reads (21%) | catalogued as rs1557621996, COSV100221149, COSV100221153; called by muse, mutect2
- POM121L12 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV101374961, COSV68692749; called by muse, mutect2, varscan2
- PON3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs375284349; called by muse, mutect2, varscan2
- POU6F1 | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV61326520; called by muse, mutect2, varscan2
- PPIL2 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58606100; called by muse, mutect2, varscan2
- PRAMEF17 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 134/192 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs989031993; called by muse, mutect2, varscan2
- PRICKLE2 | c.880G>A p.E294K (on ENST00000295902; = p.E238K on NM_198859.4) | Missense Mutation (SNP) | VAF 61/109 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV55765636; called by muse, mutect2, varscan2
- PRLR | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as COSV51494906; called by muse, mutect2, varscan2
- PROX2 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 50/56 reads (89%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV71520032; called by muse, mutect2, varscan2
- PRR3 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV64835173, COSV64835581; called by muse, mutect2, varscan2
- PRSS12 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56604143; called by muse, mutect2, varscan2
- PRUNE2 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV65040712; called by muse, mutect2, varscan2
- PSG5 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV61654048; called by muse, mutect2, varscan2
- PSG8 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs770908424, COSV60611027; called by muse, mutect2, varscan2
- PSMD1 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.145); catalogued as COSV58078123; called by muse, mutect2, varscan2
- QRICH1 | c.109A>T p.K37* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV62615243; called by muse, mutect2, varscan2
- RAB1A | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53124506; called by muse, mutect2, varscan2
- RAB27B | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs867951640, COSV50494668; called by muse, mutect2, varscan2
- RAB3GAP1 | c.179A>G p.E60G | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV51481249; called by muse, mutect2, varscan2
- RANBP2 | c.6178T>G p.L2060V | Missense Mutation (SNP) | VAF 88/399 reads (22%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.545); catalogued as COSV51699873; called by muse, mutect2, varscan2
- RASGRF2 | c.2527G>A p.D843N | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.136); catalogued as COSV54128051; called by muse, mutect2, varscan2
- REG1B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.26); PolyPhen benign (0.19); catalogued as COSV59305183; called by muse, mutect2, varscan2
- RELN | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs757182615, COSV58997854; called by muse, mutect2, varscan2
- RELN | c.983G>A p.W328* | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | catalogued as COSV58997863; called by muse, mutect2, varscan2
- RETNLB | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as COSV55465380; called by muse, mutect2, varscan2
- RFT1 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0.017); catalogued as COSV56248673; called by muse, mutect2, varscan2
- RGS9 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 19/50 reads (38%) | catalogued as rs1017448105, COSV52224721; called by muse, mutect2, varscan2
- RICTOR | c.3227C>T p.S1076F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.244); catalogued as COSV57120864, COSV99705530; called by muse, mutect2, varscan2
- RIPK4 | c.2119C>T p.R707W (on ENST00000352483; = p.R659W on NM_020639.3) | Missense Mutation (SNP) | VAF 54/79 reads (68%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs147500393; called by muse, mutect2, varscan2
- RNF180 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs771469217, COSV56960067; called by muse, mutect2, varscan2
- ROR1 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV64286475; called by muse, mutect2, varscan2
- ROS1 | c.6146C>T p.P2049L | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV63854249; called by muse, mutect2, varscan2
- RP1L1 | c.5401G>A p.G1801R | Missense Mutation (SNP) | VAF 50/188 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as rs764029725, COSV66754200; called by muse, mutect2, varscan2
- RPS26 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV62887261; called by muse, mutect2, varscan2
- RPTN | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 324/738 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV60167059; called by muse, mutect2, varscan2
- RSF1 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57839039; called by muse, mutect2, varscan2
- RSPH1 | c.660G>A p.W220* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV52319102; called by muse, mutect2, varscan2
- RTCB | c.761T>G p.V254G | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53278408, COSV99322001; called by muse, mutect2, varscan2
- RTL5 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV65453167; called by muse, mutect2, varscan2
- RYR2 | c.10356G>A p.M3452I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.316); catalogued as COSV63680342; called by muse, mutect2, varscan2
- RYR2 | c.14757G>A p.L4919= | Splice Region (SNP) | VAF 8/27 reads (30%) | catalogued as rs1558505024, COSV63680349, COSV63704855; called by mutect2, varscan2
- SAMD9 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV66074614; called by muse, mutect2, varscan2
- SAMD9L | c.3167C>T p.S1056F | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs867461861, COSV59080983; called by muse, mutect2, varscan2
- SCN11A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV56569011; called by muse, mutect2, varscan2
- SCN3B | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as rs1369143231; called by muse, mutect2
- SCN8A | c.5035G>A p.E1679K | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs796053225, COSV61980056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SELP | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55250278; called by muse, mutect2, varscan2
- SEMA5B | c.2645A>G p.N882S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.877); catalogued as COSV52095958; called by muse, mutect2, varscan2
- SERAC1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564717592, COSV65596347; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINB10 | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs865940322, COSV53072764; called by muse, mutect2, varscan2
- SF3B1 | c.3889C>T p.R1297C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267599149, COSV59209011; called by muse, mutect2, varscan2
- SGCG | c.168G>A p.W56* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as COSV54559107; called by muse, mutect2, varscan2
- SHANK1 | c.6224C>T p.S2075F | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53248333, COSV99520904; called by muse, mutect2, varscan2
- SHANK2 | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV53594911; called by muse, mutect2, varscan2
- SHE | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs756736722, COSV59071512; called by muse, mutect2, varscan2
- SKA1 | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs765582855, COSV53278630; called by muse, mutect2, varscan2
- SLAMF1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52498913; called by muse, mutect2, varscan2
- SLC12A5 | c.2543G>A p.S848N (on ENST00000454036 / NM_001134771.2; = p.S825N on NM_020708.5) | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777745429, COSV54792130; called by muse, mutect2, varscan2
- SLC22A10 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs185055343; called by muse, mutect2, varscan2
- SLC22A2 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV65266096; called by muse, mutect2, varscan2
- SLC26A7 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52591505; called by muse, mutect2, varscan2
- SLC28A1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865814792, COSV54478416; called by muse, mutect2, varscan2
- SLC28A2 | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 13/22 reads (59%) | catalogued as COSV61663788; called by muse, mutect2, varscan2
- SLC2A9 | c.1208C>T p.T403I | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.042); catalogued as COSV53319649; called by muse, mutect2, varscan2
- SLC5A8 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73310553; called by muse, mutect2, varscan2
- SLC7A10 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53503645; called by muse, mutect2, varscan2
- SLC8A1 | c.2885C>T p.S962F | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60478236; called by muse, mutect2, varscan2
- SLC8A3 | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 32/32 reads (100%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.536); catalogued as COSV100776328, COSV63520596; called by muse, mutect2, varscan2
- SLC9A4 | c.1144A>T p.N382Y | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV54832855; called by muse, mutect2, varscan2
- SLC9C2 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV62944519; called by muse, mutect2, varscan2
- SLIT2 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 95/200 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.735); catalogued as COSV56567437; called by muse, mutect2, varscan2
- SLITRK1 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs751779448, COSV65675194; called by muse, mutect2, varscan2
- SMO | c.1906G>A p.D636N | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50827480; called by muse, mutect2, varscan2
- SMTN | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV60777508; called by muse, mutect2, varscan2
- SNCAIP | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs901682731, COSV54408079; called by muse, mutect2
- SPEM2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV60366629; called by muse, mutect2, varscan2
- SPHK2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.794); catalogued as rs202163387, COSV99709386; called by muse, varscan2
- SPHK2 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.784); catalogued as COSV99709387; called by muse, mutect2, varscan2
- SPZ1 | c.1267A>T p.M423L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1468291892, COSV57063029, COSV57063343; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 46/70 reads (66%) | PolyPhen probably damaging (0.978); catalogued as rs1181452461, COSV60329415; called by muse, mutect2, varscan2
- STARD13 | c.3067C>T p.P1023S (on ENST00000336934 / NM_001243476.3; = p.P905S on NM_052851.3) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV55229716; called by muse, mutect2, varscan2
- STARD8 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1318967986, COSV52925175, COSV52934156; called by muse, mutect2, varscan2
- STAT5B | c.2206C>T p.P736S | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53180828; called by muse, mutect2, varscan2
- STK10 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51573404; called by muse, mutect2, varscan2
- STYXL2 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54804301, COSV54805986; called by muse, mutect2, varscan2
- SULT1C3 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs866697546, COSV61252236; called by muse, mutect2, varscan2
- SUSD4 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV59551998; called by muse, mutect2, varscan2
- SWT1 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145355483; called by muse, mutect2, varscan2
- SZT2 | c.4361C>T p.P1454L (on ENST00000634258 / NM_001365999.1; = p.P1397L on NM_015284.4) | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.813); catalogued as COSV65169234; called by muse, mutect2, varscan2
- TAAR5 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV57798887; called by muse, mutect2, varscan2
- TAFA2 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.346); catalogued as COSV69172315; called by muse, mutect2, varscan2
- TBX6 | c.795T>A p.N265K | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54221688; called by muse, mutect2, varscan2
- TC2N | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV61746788; called by muse, mutect2, varscan2
- TCOF1 | c.3526C>T p.P1176S (on ENST00000377797 / NM_001135243.1; = p.P1099S on NM_000356.4) | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.829); catalogued as rs1181503574, COSV60347766; called by muse, mutect2, varscan2
- TEAD4 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63280727; called by muse, mutect2, varscan2
- TEKT3 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs896973676, COSV58627247; called by muse, mutect2, varscan2
- TERB2 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV61650689; called by muse, mutect2, varscan2
- TEX47 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.025); catalogued as COSV51878781; called by muse, mutect2, varscan2
- TF | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 45/161 reads (28%) | catalogued as COSV53917586; called by muse, mutect2, varscan2
- TF | c.806C>T p.T269I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs753282540, COSV53919777; called by muse, mutect2, varscan2
- TGM5 | c.1651G>A p.D551N (on ENST00000220420 / NM_201631.4; = p.D469N on NM_004245.4) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs267604214, COSV55009799; called by muse, mutect2, varscan2
- THSD7A | c.4723C>T p.R1575W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs757798324, COSV68471700; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by muse, mutect2, varscan2
- THSD7B | c.3346C>T p.P1116S (on ENST00000272643; = p.P1114S on NM_001316349.2) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55672482, COSV55677969; called by muse, mutect2, varscan2
- TIE1 | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.236); catalogued as COSV65249319; called by muse, mutect2, varscan2
- TIMELESS | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1039931669, COSV57510797; called by muse, mutect2, varscan2
- TLE6 | c.494G>A p.R165Q (on ENST00000246112 / NM_001143986.2; = p.R42Q on NM_024760.3) | Missense Mutation (SNP) | VAF 64/131 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751721273, COSV55735136; called by muse, mutect2, varscan2
- TLL1 | c.2891G>A p.R964Q | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs771556792, COSV50274369, COSV50278762; called by muse, mutect2, varscan2
- TMCO5A | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV60464388; called by muse, mutect2, varscan2
- TMEM106B | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67543696; called by muse, mutect2, varscan2
- TMEM255B | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64703809; called by muse, mutect2, varscan2
- TNFRSF10B | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV52390969; called by muse, mutect2, varscan2
- TNN | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53425106; called by muse, mutect2, varscan2
- TNR | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV54881369; called by muse, mutect2, varscan2
- TNS3 | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV60789961; called by muse, mutect2, varscan2
- TPK1 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931909509, COSV63636997; called by muse, mutect2, varscan2
- TPO | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV61100046; called by muse, mutect2, varscan2
- TPSAB1 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV58780797; called by muse, mutect2, varscan2
- TRAV13-1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 65/75 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs751141340; called by muse, mutect2, varscan2
- TRERF1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV61670503; called by muse, mutect2, varscan2
- TRIM15 | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64989273; called by muse, mutect2, varscan2
- TRIM42 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV53882316; called by muse, mutect2, varscan2
- TRIP4 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56029795; called by muse, mutect2, varscan2
- TRIT1 | c.994C>A p.R332S | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV57547947; called by muse, mutect2, varscan2
- TRPC1 | c.1444G>A p.D482N (on ENST00000476941 / NM_001251845.2; = p.D448N on NM_003304.4) | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV56424558; called by muse, mutect2, varscan2
- TRPC5 | c.2017C>T p.L673F | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV53288611; called by muse, mutect2, varscan2
- TRPC6 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60253459; called by muse, mutect2, varscan2
- TSHZ3 | c.2359G>A p.D787N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs377119189, COSV53669573; called by muse, mutect2, varscan2
- TSPEAR | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV59959260; called by muse, mutect2, varscan2
- TTN | c.101692G>A p.E33898K (on ENST00000591111; = p.E26474K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | PolyPhen benign (0.259); catalogued as COSV60001792; called by muse, mutect2
- TTN | c.39097G>A p.E13033K (on ENST00000591111; = p.E5609K on NM_003319.4) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | PolyPhen benign (0.385); catalogued as rs794729432, COSV60001880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.34766C>T p.P11589L (on ENST00000591111; = p.P10662L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | PolyPhen benign (0.003); catalogued as rs777572812, COSV60001910; called by muse, mutect2, varscan2
- TTN | c.22436G>A p.R7479Q (on ENST00000591111; = p.R6552Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | PolyPhen benign (0.293); catalogued as rs267599059; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.14575G>A p.D4859N (on ENST00000591111; = p.D3932N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | PolyPhen benign (0.003); catalogued as COSV60001937, COSV60184417; called by muse, mutect2, varscan2
- TTN | c.12932C>T p.S4311F (on ENST00000591111; = p.S4265F on NM_003319.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as rs794729602, COSV100591096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TWSG1 | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV50814880; called by muse, mutect2, varscan2
- UBE2A | c.123C>T p.F41= | Splice Region (SNP) | VAF 38/80 reads (48%) | catalogued as COSV60636497; called by muse, mutect2, varscan2
- UBQLN3 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs146563055; called by muse, mutect2, varscan2
- UBR3 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55847973; called by muse, mutect2, varscan2
- UGT2A1 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54138822; called by muse, mutect2, varscan2
- UGT2A2 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.066); catalogued as rs756886134, COSV54140461, COSV99684146; called by muse, mutect2, varscan2
- UGT2B10 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55319921; called by muse, mutect2, varscan2
- UGT2B11 | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 30/76 reads (39%) | catalogued as COSV71422936; called by muse, mutect2, varscan2
- UGT2B28 | c.14G>A p.W5* | Nonsense Mutation (SNP) | VAF 56/140 reads (40%) | catalogued as COSV59431520; called by muse, mutect2, varscan2
- UGT3A1 | c.987G>A p.W329* | Nonsense Mutation (SNP) | VAF 22/41 reads (54%) | catalogued as COSV57097480; called by muse, mutect2, varscan2
- UPB1 | c.680G>A p.R227K | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58113229; called by muse, mutect2, varscan2
- USP16 | c.2170C>T p.P724S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV57624962; called by muse, mutect2, varscan2
- USP17L2 | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV61555787; called by muse, mutect2
- USP4 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV55536456; called by muse, mutect2, varscan2
- USP9X | c.5075C>T p.S1692L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV61068446; called by muse, mutect2, varscan2
- UTRN | c.5014G>A p.E1672K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV62333313; called by muse, mutect2, varscan2
- VCAM1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs762937799, COSV54118616; called by muse, mutect2, varscan2
- VCPIP1 | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 52/93 reads (56%) | catalogued as COSV60046898; called by muse, mutect2, varscan2
- VEGFC | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54595276; called by muse, mutect2, varscan2
- VEGFD | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV52909474; called by muse, mutect2, varscan2
- VPS35 | c.1161-2A>T p.X387_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | catalogued as COSV54478022; called by muse, mutect2, varscan2
- VSTM4 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60525593; called by muse, mutect2, varscan2
- WDR13 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.486); catalogued as COSV54331588; called by muse, mutect2, varscan2
- WDR44 | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54162735; called by muse, mutect2, varscan2
- WDR7 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54351766; called by muse, mutect2, varscan2
- WDR75 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as rs867024384, COSV59105392; called by muse, mutect2, varscan2
- XIRP2 | c.8594G>A p.G2865E (on ENST00000628543; = p.G3040E on NM_152381.6) | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV54695150; called by muse, mutect2, varscan2
- XPNPEP3 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 119/211 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs763808975, COSV63210083; called by muse, mutect2, varscan2
- ZBED9 | c.1985G>A p.R662K | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); catalogued as COSV71729347; called by muse, mutect2, varscan2
- ZC4H2 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.8); PolyPhen benign (0.096); catalogued as rs1484560905, COSV100564932, COSV62003071; called by muse, mutect2, varscan2
- ZCCHC13 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs750647440, COSV59866182; called by muse, mutect2, varscan2
- ZDHHC13 | c.548A>T p.Q183L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV67980842; called by muse, mutect2, varscan2
- ZDHHC4 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60106379; called by muse, mutect2, varscan2
- ZFHX4 | c.4766A>T p.D1589V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50697655; called by muse, mutect2, varscan2
- ZFHX4 | c.8452G>A p.E2818K | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50697960; called by muse, mutect2, varscan2
- ZFP64 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs375838246; called by muse, mutect2, varscan2
- ZMYM3 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100078376, COSV58737427, COSV58737515; called by muse, mutect2, varscan2
- ZMYM4 | c.2077C>A p.L693I | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.628); catalogued as COSV58909508, COSV58914902; called by muse, mutect2, varscan2
- ZNF223 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV71571858; called by muse, mutect2, varscan2
- ZNF229 | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52160990; called by muse, mutect2, varscan2
- ZNF318 | c.4336C>T p.P1446S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.974); catalogued as COSV58932014; called by muse, mutect2, varscan2
- ZNF385D | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as rs752571574, COSV55752607; called by muse, mutect2, varscan2
- ZNF404 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs200263609; called by muse, mutect2, varscan2
- ZNF41 | c.1801C>T p.H601Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57442236; called by muse, mutect2, varscan2
- ZNF445 | c.2254C>T p.P752S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as COSV68538769; called by muse, mutect2, varscan2
- ZNF490 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as COSV61007760, COSV61008254; called by muse, mutect2, varscan2
- ZNF711 | c.2037A>T p.K679N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV52153313; called by muse, mutect2, varscan2
- ZNF75D | c.229T>C p.W77R | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV66132648; called by muse, mutect2, varscan2
- ZNF77 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as rs267605401, COSV100094474; called by muse, mutect2, varscan2
- ZNF77 | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.17); catalogued as COSV100094477; called by muse, mutect2, varscan2
- ZNF827 | c.573G>A p.W191* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV65226433; called by muse, mutect2, varscan2
- ZNF835 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73379382; called by muse, mutect2, varscan2
- ZNF875 | c.1667G>A p.R556K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs751142690, COSV60990973; called by muse, mutect2, varscan2
- ZPBP2 | c.719G>A p.R240Q (on ENST00000348931 / NM_199321.3; = p.R218Q on NM_198844.3) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.834); catalogued as rs376495488; called by muse, mutect2, varscan2
- ZSWIM4 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV54321126; called by muse, mutect2, varscan2
- AKR1C8P | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ARHGEF2 | c.331del p.R111Efs*36 (on ENST00000361247 / NM_001162383.2; = p.R84Efs*36 on NM_004723.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- ATRIP | c.1032_1033del p.L345Afs*22 | Frame Shift Del (DEL) | VAF 43/108 reads (40%) | called by mutect2, pindel, varscan2
- FCGBP | c.4507A>C p.S1503R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- NR4A1 | c.346del p.L116* | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.1642_1654del p.I548Afs*5 | Frame Shift Del (DEL) | VAF 9/36 reads (25%) | called by mutect2, pindel, varscan2
- TNXB | c.10309del p.Q3437Rfs*84 (on ENST00000647633; = p.Q3190Rfs*84 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/132 reads (11%) | called by pindel, varscan2
- ABCA1 | c.1380C>T p.A460= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV66065667; called by muse, mutect2, varscan2
- ABCA2 | c.5256C>T p.I1752= (on ENST00000614293; = p.I1722= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/41 reads (83%) | catalogued as rs200702540, COSV55800227; called by muse, mutect2, varscan2
- ABCC6 | c.3690C>T p.I1230= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs368931767; called by muse, mutect2, varscan2
- AC126283.2 | c.627C>T p.F209= | Silent (SNP) | VAF 32/87 reads (37%) | catalogued as rs868123583, COSV67098265; called by muse, mutect2, varscan2
- ADAMTS15 | c.513C>T p.T171= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs763988109, COSV54504896; called by muse, mutect2, varscan2
- ADAMTS16 | c.2598C>T p.P866= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV99941196; called by muse, mutect2, varscan2
- AFF2 | c.1881G>A p.G627= | Silent (SNP) | VAF 60/142 reads (42%) | catalogued as rs868938185, COSV53983439; called by muse, mutect2, varscan2
- ARHGAP20 | c.1452C>T p.L484= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as COSV52809879; called by muse, mutect2, varscan2
- ARHGAP5 | c.1791C>T p.N597= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs1566660856, COSV61535133; called by muse, mutect2, varscan2
- ARHGEF3 | c.765C>T p.F255= | Silent (SNP) | VAF 80/133 reads (60%) | catalogued as COSV56325699; called by muse, mutect2, varscan2
- ARID1A | c.5863C>T p.L1955= | Silent (SNP) | VAF 79/124 reads (64%) | catalogued as COSV61375991; called by muse, mutect2, varscan2
- ATP5F1B | c.741C>T p.Y247= | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV56260796; called by muse, mutect2, varscan2
- C1orf141 | c.735C>T p.F245= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs267598698, COSV63992364; called by muse, mutect2, varscan2
- CA10 | c.838C>T p.L280= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as COSV53346354, COSV53347800; called by muse, varscan2
- CACNA1C | c.2844T>C p.I948= | Silent (SNP) | VAF 78/165 reads (47%) | catalogued as COSV59711316; called by muse, mutect2, varscan2
- CAMK1D | c.99C>T p.A33= | Silent (SNP) | VAF 34/39 reads (87%) | catalogued as COSV66610486; called by muse, mutect2, varscan2
- CAPN2 | c.1008C>T p.S336= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV54334310; called by muse, mutect2, varscan2
- CARD6 | c.1023G>A p.R341= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV54564618, COSV54565761; called by muse, mutect2, varscan2
- CASZ1 | c.771C>T p.P257= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV59734595; called by muse, mutect2, varscan2
- CATIP | c.987C>T p.S329= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV56822529; called by muse, mutect2, varscan2
- CCDC158 | c.1584G>A p.L528= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV66355560, COSV66355643; called by muse, mutect2, varscan2
- CCNB3 | c.117G>A p.T39= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV52072521; called by muse, mutect2, varscan2
- CD1B | c.843G>A p.V281= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV63804171; called by muse, mutect2, varscan2
- CD2 | c.274C>T p.L92= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV65643450; called by muse, mutect2, varscan2
- CDH6 | c.1317G>A p.S439= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs774760334, COSV54064343; called by muse, mutect2, varscan2
- CDKN1A | c.474C>T p.I158= | Silent (SNP) | VAF 168/327 reads (51%) | catalogued as rs772087100, COSV55188541, COSV55189214; called by muse, mutect2, varscan2
- CEACAM19 | c.552G>A p.R184= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs923420749, COSV100715447; called by muse, mutect2, varscan2
- CEP128 | c.1872C>T p.A624= | Silent (SNP) | VAF 46/55 reads (84%) | catalogued as COSV55374370; called by muse, mutect2, varscan2
- CFTR | c.945C>T p.F315= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as rs1165242377, COSV50041081; called by muse, mutect2, varscan2
- CHD5 | c.4941C>T p.I1647= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV52412819; called by muse, mutect2, varscan2
- CHSY1 | c.2247C>T p.V749= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV54252803; called by muse, mutect2, varscan2
- CIDEB | c.135G>A p.R45= | Silent (SNP) | VAF 42/48 reads (88%) | catalogued as COSV51865451; called by muse, mutect2, varscan2
- CLRN2 | c.198C>T p.F66= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as COSV55549827; called by muse, mutect2, varscan2
- COL12A1 | c.1482G>A p.L494= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs568403703, COSV59394314; called by muse, mutect2, varscan2
- COL15A1 | c.2118G>A p.G706= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as COSV66640926; called by muse, mutect2, varscan2
- COL7A1 | c.5895G>A p.E1965= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV60394421; called by muse, mutect2, varscan2
- CPNE5 | c.795G>A p.G265= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as COSV55196031; called by muse, mutect2, varscan2
- CSF1 | c.591C>T p.I197= | Silent (SNP) | VAF 86/129 reads (67%) | catalogued as rs140214194; called by muse, mutect2, varscan2
- CTNND2 | c.120G>A p.G40= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV58882618; called by muse, varscan2
- CYP4F11 | c.1278G>A p.G426= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV56126605; called by muse, mutect2, varscan2
- DBF4B | c.1725C>T p.T575= | Silent (SNP) | VAF 25/110 reads (23%) | catalogued as COSV100154520; called by muse, mutect2, varscan2
- DCLRE1A | c.198C>T p.P66= | Silent (SNP) | VAF 80/89 reads (90%) | catalogued as COSV63748546; called by muse, mutect2, varscan2
- DCLRE1C | c.420G>A p.A140= (on ENST00000378278 / NM_001350965.2; = p.A25= on NM_022487.4) | Silent (SNP) | VAF 76/89 reads (85%) | catalogued as rs146832860, COSV63182724; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DDX11 | c.1470C>T p.I490= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- DHDH | c.420C>T p.A140= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as COSV55481978; called by muse, mutect2, varscan2
- DMD | c.9828C>T p.I3276= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs757899883, COSV58905745; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.8091C>T p.I2697= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs754038916, COSV54219408, COSV54231114; called by muse, mutect2, varscan2
- DNAH5 | c.5751G>A p.L1917= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs868033774, COSV54219420; called by muse, mutect2, varscan2
- DNAH5 | c.1878G>A p.K626= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV54219430; called by muse, mutect2, varscan2
- DNMT3B | c.420C>T p.F140= | Silent (SNP) | VAF 33/73 reads (45%) | catalogued as COSV52417515; called by muse, mutect2, varscan2
- DPP6 | c.1470C>T p.I490= (on ENST00000377770 / NM_001364500.2; = p.I428= on NM_001936.5) | Silent (SNP) | VAF 15/22 reads (68%) | catalogued as rs1390998701, COSV59608503; called by muse, mutect2, varscan2
- DSG4 | c.1698C>T p.I566= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV57390791; called by muse, mutect2, varscan2
- DZIP1 | c.951G>A p.S317= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs760394767, COSV61264062; called by muse, mutect2, varscan2
- EDNRA | c.276C>T p.I92= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as rs199631962; called by muse, mutect2, varscan2
- EIF3G | c.336C>T p.P112= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53458091; called by muse, mutect2, varscan2
- EPHA3 | c.2241C>T p.L747= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs1370663734, COSV60702326, COSV60707950; called by muse, mutect2, varscan2
- EPHA7 | c.1458G>A p.R486= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1178361521, COSV100993710; called by muse, mutect2, varscan2
- EPHB6 | c.2739G>A p.V913= | Silent (SNP) | VAF 103/194 reads (53%) | catalogued as COSV63891434; called by muse, mutect2, varscan2
- ERICH6 | c.1809C>T p.I603= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as COSV55799986; called by muse, mutect2, varscan2
- ERN2 | c.2337C>T p.P779= | Silent (SNP) | VAF 139/286 reads (49%) | catalogued as COSV99891525; called by muse, mutect2, varscan2
- F8 | c.4440C>T p.S1480= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV64272311; called by muse, mutect2, varscan2
- FAM117A | c.1296C>T p.F432= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs771259538, COSV53602827, COSV53603794; called by muse, mutect2, varscan2
- FAM83B | c.2703G>A p.E901= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV60921441; called by muse, mutect2, varscan2
- FANCD2 | c.3960C>T p.H1320= | Silent (SNP) | VAF 104/186 reads (56%) | catalogued as COSV55036532; called by muse, mutect2, varscan2
- FAT1 | c.13200C>T p.F4400= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as COSV71673460, COSV71674701; called by muse, mutect2, varscan2
- FAT1 | c.11202C>T p.F3734= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV101499348, COSV71674423; called by muse, mutect2, varscan2
- FAT3 | c.11883G>A p.L3961= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV53101490; called by muse, mutect2, varscan2
- FAT4 | c.10056G>A p.K3352= | Silent (SNP) | VAF 40/73 reads (55%) | catalogued as COSV58680942; called by muse, mutect2, varscan2
- FER1L6 | c.4485C>T p.H1495= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV67549476; called by muse, mutect2, varscan2
- FHL5 | c.51G>A p.G17= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV58737044; called by muse, mutect2, varscan2
- FILIP1 | c.1911G>A p.E637= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as COSV52727798; called by muse, mutect2, varscan2
- FLG2 | c.3951G>A p.Q1317= | Silent (SNP) | VAF 80/189 reads (42%) | catalogued as COSV66168113; called by muse, mutect2, varscan2
- FLNA | c.1179C>T p.P393= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV61041680; called by muse, mutect2, varscan2
- FOXK2 | c.522C>T p.A174= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs371316297; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.393G>A p.K131= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV58552250; called by muse, mutect2
- FPR2 | c.354C>T p.F118= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV60672022; called by muse, mutect2, varscan2
- GALNT16 | c.1011C>T p.I337= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as rs556954532, COSV61885700; called by muse, mutect2, varscan2
- GAP43 | c.330G>A p.E110= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV59343717; called by muse, mutect2, varscan2
- GAREM1 | c.1029C>T p.V343= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as COSV52508406; called by muse, mutect2, varscan2
- GBA3 | c.1344C>A p.V448= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as rs1560236807, COSV72438041, COSV72438235; called by muse, mutect2, varscan2
- GEMIN4 | c.2004C>T p.D668= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1457338248, COSV56745596; called by muse, mutect2, varscan2
- GIMAP7 | c.420G>A p.Q140= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV57959218; called by muse, mutect2, varscan2
- GIPC3 | c.660G>A p.E220= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV59258836; called by muse, mutect2, varscan2
- GK2 | c.78G>A p.L26= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs145465808; called by muse, mutect2, varscan2
- GMIP | c.2250C>T p.I750= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs138372356; called by muse, mutect2, varscan2
- GON4L | c.42C>T p.S14= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV55192243; called by muse, mutect2, varscan2
- GRAMD2A | c.828G>A p.K276= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100550830, COSV59033397; called by muse, mutect2, varscan2
- H2AB1 | c.54G>T p.R18= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57704952; called by mutect2, varscan2
- HCN1 | c.2400G>A p.L800= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs1261296520, COSV57505810; called by muse, mutect2, varscan2
- HHLA2 | c.453G>A p.R151= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV63316842; called by muse, mutect2, varscan2
- HSD17B6 | c.210G>A p.R70= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV59107665; called by muse, mutect2, varscan2
- HSF2BP | c.162C>T p.F54= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs1158727165, COSV52355887; called by muse, mutect2, varscan2
- HTR4 | c.915C>T p.S305= | Silent (SNP) | VAF 17/17 reads (100%) | catalogued as rs766327249, COSV58793624; called by muse, mutect2, varscan2
- ILDR2 | c.1047C>T p.F349= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV54830325; called by muse, mutect2, varscan2
- INTS13 | c.621C>T p.I207= | Silent (SNP) | VAF 21/29 reads (72%) | catalogued as COSV53902284; called by muse, mutect2, varscan2
- ITGA5 | c.3057C>T p.I1019= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV53217211; called by muse, mutect2, varscan2
- ITGB5 | c.1593C>T p.N531= | Silent (SNP) | VAF 53/93 reads (57%) | catalogued as COSV56148473; called by muse, mutect2
- ITIH6 | c.1215G>A p.T405= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs372848668, COSV54488434; called by muse, mutect2, varscan2
- KBTBD12 | c.918G>A p.R306= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV59679008; called by muse, mutect2, varscan2
- KCNA10 | c.1068C>T p.R356= | Silent (SNP) | VAF 72/118 reads (61%) | catalogued as COSV63904568, COSV63904640; called by muse, mutect2, varscan2
- KCNJ5 | c.570C>T p.I190= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV57965356; called by muse, mutect2, varscan2
- KCNK5 | c.501C>T p.I167= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs964474709, COSV63988816; called by muse, mutect2, varscan2
- KDM5B | c.3513C>T p.L1171= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV52507037; called by muse, mutect2, varscan2
- KIF5C | c.882G>A p.G294= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs777704019, COSV68479692; called by muse, mutect2, varscan2
- KLK4 | c.435G>A p.G145= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as rs1568514287, COSV60676161; called by muse, mutect2, varscan2
- KMT2C | c.12954C>T p.V4318= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs189172605, COSV51422283; called by muse, mutect2, varscan2
- KRTAP10-10 | c.177C>T p.P59= | Silent (SNP) | VAF 63/99 reads (64%) | catalogued as COSV59959268; called by muse, mutect2, varscan2
- LETM1 | c.2037G>A p.K679= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100245507, COSV57100126; called by muse, mutect2
- LILRA4 | c.744C>T p.V248= | Silent (SNP) | VAF 20/30 reads (67%) | catalogued as rs771692815, COSV52491704; called by muse, mutect2, varscan2
- LIMK2 | c.546G>T p.V182= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV59182165; called by muse, mutect2, varscan2
- LIN7A | c.225G>A p.T75= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs780444755, COSV54017815; called by muse, mutect2, varscan2
- LPO | c.1908C>T p.F636= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV51858343; called by muse, mutect2, varscan2
- MAML2 | c.3205T>C p.L1069= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV73263234; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2538C>T p.I846= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV51719246; called by muse, mutect2, varscan2
- MDFIC | c.468C>T p.S156= | Silent (SNP) | VAF 22/45 reads (49%) | catalogued as COSV99995136; called by muse, mutect2, varscan2
- MEFV | c.1224G>A p.R408= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV54820886; called by muse, mutect2, varscan2
- MGA | c.9024C>T p.L3008= (on ENST00000219905 / NM_001164273.1; = p.L2799= on NM_001080541.2) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV54952515; called by muse, mutect2, varscan2
- MINAR1 | c.1824G>A p.R608= | Silent (SNP) | VAF 32/59 reads (54%) | catalogued as rs772119826, COSV59582330; called by muse, mutect2, varscan2
- MPO | c.1347C>T p.I449= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs746831572, COSV56561153, COSV99832387; called by muse, mutect2, varscan2
- MROH2B | c.3078C>T p.A1026= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs768202807, COSV68183154; called by muse, mutect2, varscan2
- MROH8 | c.411C>T p.S137= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV54119355; called by muse, mutect2, varscan2
- MSR1 | c.714G>A p.Q238= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV50509955; called by muse, mutect2, varscan2
- MUC16 | c.32139C>T p.A10713= | Silent (SNP) | VAF 82/181 reads (45%) | catalogued as rs1287854838, COSV67460418; called by muse, mutect2, varscan2
- MUC16 | c.28173C>T p.S9391= | Silent (SNP) | VAF 41/80 reads (51%) | catalogued as COSV67461339; called by muse, mutect2, varscan2
- MUC16 | c.27054G>A p.K9018= | Silent (SNP) | VAF 25/61 reads (41%) | catalogued as rs772072388, COSV67461341, COSV67489962; called by muse, mutect2, varscan2
- MUC2 | c.1548G>A p.L516= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs1263678458; called by muse, mutect2, varscan2
- MYBPC2 | c.2268G>A p.K756= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV63094875; called by muse, varscan2
- MYH6 | c.2652G>A p.Q884= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as COSV62449640; called by muse, mutect2, varscan2
- MYH8 | c.3066C>T p.I1022= | Silent (SNP) | VAF 60/117 reads (51%) | catalogued as rs780766097, COSV67963611, COSV67966225; called by muse, mutect2, varscan2
- MYO18B | c.7572C>T p.I2524= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV59131832; called by muse, varscan2
- MYO18B | c.7656G>A p.R2552= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV59131838; called by muse, varscan2
- MYO3B | c.165G>A p.V55= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV58701281; called by muse, mutect2, varscan2
- NAA80 | c.207C>T p.P69= (on ENST00000417393 / NM_001200018.2; = p.P91= on NM_012191.4) | Silent (SNP) | VAF 38/56 reads (68%) | catalogued as rs35565547, COSV56499174; called by muse, mutect2, varscan2
- NAGA | c.294C>T p.F98= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as COSV67169904; called by muse, mutect2
- NALCN | c.3966G>A p.K1322= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV51930904; called by muse, mutect2, varscan2
161 further variants in this file (0 protein-altering or splice-affecting, 138 silent, 23 other) are not listed here.
